Somatic mutation profile of tumor specimen TCGA-G4-6322-01A (aliquot TCGA-G4-6322-01A-11D-1719-10) from TCGA case TCGA-G4-6322, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.2 years (23,825 days).
Specimen TCGA-G4-6322-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76028c89-9cbf-4a09-a9c8-b611d4026c72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6322-10A (Blood Derived Normal), aliquot TCGA-G4-6322-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbc223e1-a6d7-495d-b6bd-60353d6dfb15

The open-access MAF lists 95 somatic variants for this specimen: 69 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Nonsense Mutation 6, Splice Region 2, In Frame Ins 2, Frame Shift Del 2, Intron 1, RNA 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2804dup p.Y935* | Nonsense Mutation (INS) | VAF 45/126 reads (36%) | hotspot (GDC flag); catalogued as rs863225332, CI023287, CI991958, COSV57344655; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- APC | c.4067C>G p.S1356* | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as rs1554085480, COSV57325773, COSV57330189, COSV57333960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 93/214 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 128/302 reads (42%) | catalogued as rs797045057, CM043040, CM051589, COSV61774888; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145877597, CM053385, COSV99416661; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121917935, CM067004, CM113275, COSV57675833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 110/148 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875227, CM122492, COSV100759471, COSV60785471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1843_1844insTGA p.R615delinsLS | In Frame Ins (INS) | VAF 43/138 reads (31%) | catalogued as COSV60693602; called by mutect2, pindel, varscan2
- ACAN | c.5789G>T p.S1930I | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61368827; called by muse, mutect2, varscan2
- ADGRG4 | c.8943C>A p.F2981L | Missense Mutation (SNP) | VAF 115/139 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs779352446, COSV54966234; called by muse, mutect2, varscan2
- ANO8 | c.2116A>C p.T706P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV50173684, COSV99344829; called by muse, mutect2, varscan2
- ANXA10 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV63740340; called by muse, mutect2, varscan2
- ARHGAP21 | c.4414A>G p.I1472V | Missense Mutation (SNP) | VAF 62/558 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100256561; called by muse, mutect2, varscan2
- ARHGAP28 | c.776C>T p.P259L (on ENST00000383472 / NM_001366230.1; = p.P100L on NM_001010000.3) | Missense Mutation (SNP) | VAF 166/322 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1223142867, COSV51645969; called by muse, mutect2, varscan2
- BPIFA2 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV53612716; called by muse, mutect2, varscan2
- CARF | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.292); catalogued as rs745904615, COSV57549905; called by muse, mutect2, varscan2
- CCDC103 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53653628; called by muse, mutect2, varscan2
- CCNA1 | c.362C>A p.A121E | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99714803; called by muse, mutect2, varscan2
- CIITA | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs757009223, COSV60857540; called by muse, mutect2, varscan2
- CREB3L2 | c.1485C>T p.H495= | Splice Region (SNP) | VAF 33/120 reads (28%) | catalogued as rs1410829863, COSV57799949; called by muse, mutect2, varscan2
- CSRNP2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57335168, COSV99950467; called by muse, mutect2
- CYLC1 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 205/239 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61415703; called by muse, mutect2, varscan2
- DLC1 | c.1820C>T p.A607V (on ENST00000276297 / NM_001348081.2; = p.A170V on NM_006094.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs929788084, COSV52326811; called by muse, mutect2, varscan2
- DNAH1 | c.1092C>A p.C364* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV70228244, COSV70235932; called by muse, mutect2, varscan2
- EP300 | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV54344815; called by muse, mutect2, varscan2
- FAIM2 | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs776668988, COSV57737688, COSV57741066; called by muse, mutect2, varscan2
- FAM53C | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750874638, COSV53511555; called by muse, mutect2, varscan2
- FAT4 | c.13543G>A p.A4515T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs369929089; called by muse, mutect2, varscan2
- FIGNL2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV73729298; called by muse, mutect2, varscan2
- FMNL2 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56503907, COSV99979140; called by muse, mutect2, varscan2
- FOXE3 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs371048362, CM025342, COSV100624047; called by muse, mutect2, varscan2
- FRAS1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV53645466; called by muse, mutect2, varscan2
- GABRA5 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV59485637; called by muse, mutect2, varscan2
- GLE1 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012757; called by muse, mutect2, varscan2
- HECW1 | c.774C>A p.N258K | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67839491; called by muse, mutect2, varscan2
- IDH1 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 192/403 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1226814453, COSV61626228; called by muse, mutect2, varscan2
- KDM6B | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as rs1187763093, COSV99642113; called by muse, mutect2, varscan2
- KIAA0825 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56959616; called by muse, mutect2, varscan2
- KIF13A | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); catalogued as rs751899598, COSV52465016; called by muse, mutect2, varscan2
- LRRC49 | c.1746dup p.P583Tfs*9 | Frame Shift Ins (INS) | VAF 154/386 reads (40%) | catalogued as rs1365554814; called by mutect2, varscan2
- MASP2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs78019538; called by muse, mutect2, varscan2
- MRGPRF | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs1315216900, COSV57995736; called by muse, mutect2
- MTOR | c.7322G>A p.R2441Q | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1413993125, COSV63875719; called by muse, mutect2, varscan2
- MYCBPAP | c.468G>A p.Q156= | Splice Region (SNP) | VAF 86/242 reads (36%) | catalogued as COSV60412055; called by muse, mutect2
- MYH6 | c.4478C>T p.S1493F | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1364111488, COSV62454194; called by muse, mutect2, varscan2
- NT5DC3 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs774079019, COSV67322812; called by muse, mutect2, varscan2
- NUP214 | c.5869C>T p.Q1957* | Nonsense Mutation (SNP) | VAF 59/184 reads (32%) | catalogued as COSV100845373; called by muse, mutect2, varscan2
- NYNRIN | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as rs201881306, COSV66842428; called by muse, mutect2, varscan2
- OR9G1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs373762637; called by muse, mutect2
- PCDHB14 | c.1594G>C p.G532R | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.068); catalogued as COSV53391202; called by muse, mutect2, varscan2
- PCDHGB6 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54026860; called by muse, mutect2, varscan2
- PCSK9 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777111934, COSV100135497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRMT6 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs779702003, COSV63656461; called by muse, mutect2, varscan2
- PRTG | c.3287G>A p.G1096D | Missense Mutation (SNP) | VAF 120/152 reads (79%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs780931139, COSV66840567; called by muse, mutect2, varscan2
- RBMXL2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60981627; called by muse, mutect2, varscan2
- RYR1 | c.4964G>A p.R1655H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.077); catalogued as rs781159223, COSV100617166, COSV62105166; called by muse, mutect2, varscan2
- RYR3 | c.8936G>A p.R2979Q (on ENST00000389232; = p.R2980Q on NM_001036.6) | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs200346049, COSV66785492; called by muse, mutect2, varscan2
- SHISAL1 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs774297018, COSV66988811; called by muse, mutect2, varscan2
- SLC34A2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101158401, COSV65942977; called by muse, mutect2, varscan2
- SLC36A1 | c.257T>G p.I86S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99695709; called by muse, mutect2, varscan2
- STRN3 | c.1849del p.E617Kfs*24 (on ENST00000357479 / NM_001083893.2; = p.E533Kfs*24 on NM_014574.4) | Frame Shift Del (DEL) | VAF 86/434 reads (20%) | catalogued as COSV62581886; called by mutect2, pindel, varscan2
- TRAF3IP1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs766887017, COSV64854205; called by muse, mutect2, varscan2
- UBE2G2 | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446162; called by muse, mutect2, varscan2
- ZBTB7B | c.823G>A p.G275S (on ENST00000292176; = p.G309S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV52694262, COSV52694733; called by muse, mutect2, varscan2
- ZNF443 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 166/393 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1459062533, COSV56894199; called by muse, mutect2, varscan2
- CTC1 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMTC4 | c.704_705insAAA p.D235delinsEN (on ENST00000376234 / NM_001350577.2; = p.D254delinsEN on NM_032813.5 and 2 other RefSeq transcripts) | In Frame Ins (INS) | VAF 75/170 reads (44%) | called by mutect2, pindel, varscan2
- ZNF404 | c.1035_1036del p.H345Qfs*5 | Frame Shift Del (DEL) | VAF 53/136 reads (39%) | called by mutect2, varscan2
- AARD | c.99G>A p.A33= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV65600402; called by muse, mutect2, varscan2
- AC011462.1 | c.1071C>T p.P357= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV54196900; called by muse, mutect2
- CAPN10 | c.303C>T p.A101= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as rs1034523415, COSV99550498; called by muse, mutect2, varscan2
- DCTN1 | c.2769G>A p.P923= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as rs751246549, COSV100720889, COSV62621454; called by muse, mutect2, varscan2
- DEF6 | c.81C>G p.S27= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV57355351; called by muse, mutect2, varscan2
- EGFLAM | c.759C>T p.T253= | Silent (SNP) | VAF 169/341 reads (50%) | catalogued as rs936189926, COSV59316357; called by muse, mutect2, varscan2
- FGD3 | c.663G>A p.T221= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV61599810; called by muse, mutect2, varscan2
- FOXP2 | c.2088T>C p.S696= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV63493649; called by muse, mutect2, varscan2
- FREM2 | c.339C>T p.D113= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV54832485; called by muse, mutect2, varscan2
- H1-2 | c.237T>C p.R79= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as COSV59191341, COSV59192401; called by muse, mutect2, varscan2
- H1-4 | c.459G>A p.K153= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as rs759116050, COSV56801533, COSV56803168; called by muse, mutect2, varscan2
- L3MBTL3 | c.2133C>T p.D711= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs775183739, COSV62388831; called by muse, mutect2, varscan2
- LRRC6 | c.996C>T p.I332= | Silent (SNP) | VAF 79/212 reads (37%) | catalogued as COSV51542997; called by muse, mutect2, varscan2
- NLRP2 | c.897G>A p.A299= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs373171651, COSV99672581; called by muse, mutect2, varscan2
- NPIPB15 | c.1110G>A p.P370= | Silent (SNP) | VAF 82/417 reads (20%) | catalogued as rs781443385; called by muse, mutect2, varscan2
- PNMA8B | c.1476C>T p.A492= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs1285616311, COSV66537685; called by muse, mutect2, varscan2
- RYR2 | c.1320G>A p.A440= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs887478410, COSV63712174; called by muse, mutect2, varscan2
- SACS | c.8883G>A p.S2961= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs1463204431, COSV66546898; called by muse, mutect2, varscan2
- SLC25A32 | c.660C>T p.A220= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99884627; called by muse, mutect2, varscan2
- STXBP4 | c.837C>T p.S279= | Silent (SNP) | VAF 36/358 reads (10%) | catalogued as COSV54843768; called by muse, mutect2
- TTC17 | c.474T>A p.P158= | Silent (SNP) | VAF 61/977 reads (6%) | catalogued as COSV99235815; called by muse, mutect2
- UGGT2 | c.966C>T p.S322= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs202152790, COSV65026011; called by muse, mutect2, varscan2
- ZFR2 | c.132C>T p.A44= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as rs1395832020, COSV53603077; called by muse, mutect2, varscan2
- HERC2P3 | n.2192G>A | RNA (SNP) | VAF 24/28 reads (86%) | catalogued as rs1284382095; called by mutect2, varscan2
- MIR1270 | chr19:20397701 G>T | 3'Flank (SNP) | VAF 37/96 reads (39%) | catalogued as rs935196014; called by muse, mutect2, varscan2
- TTN | c.10361-5056C>T | Intron (SNP) | VAF 161/397 reads (41%) | catalogued as rs755405732, COSV100629391, COSV60220845; called by muse, mutect2, varscan2
